Gene-level copy-number profile of tumor specimen TCGA-HU-A4G3-01A from TCGA case TCGA-HU-A4G3, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.9 years (20,064 days).
Specimen TCGA-HU-A4G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d07b4346-cb34-4c26-bcbd-d38a6e343993.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4G3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/4a5ea691-8ebd-4e34-9f4d-3ec59a199ff1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 2,464; copy number 2: 56,665; copy number 3: 675.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,069,168–3,438,621, 1 gene (within-gene range 0–2): PRDM16.
- chr1:3,205,988–3,323,149, 3 genes: AL512383.1, AL590438.1, AL354743.2.
- chr2:205,253,304–205,253,503, 1 gene: AC008171.1.
- chr3:169,083,499–169,663,775, 4 genes (within-gene range 0–2): MECOM, MECOM-AS1, RPL22P1, AC007849.1.
- chr4:91,319,034–91,325,306, 1 gene: AC074124.1.
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.
- chr6:1,623,806–2,245,605, 1 gene (within-gene range 0–2): GMDS.
- chr21:25,880,550–26,171,128, 1 gene (within-gene range 0–2): APP.
- chr21:26,158,091–26,175,824, 1 gene: AP001439.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 45. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
